Somatic mutation profile of tumor specimen TCGA-KK-A8I9-01A (aliquot TCGA-KK-A8I9-01A-11D-A364-08) from TCGA case TCGA-KK-A8I9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.0 years (22,295 days).
Specimen TCGA-KK-A8I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe20a06b-3471-48e1-8d2b-ff1251a05baf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8I9-11A (Solid Tissue Normal), aliquot TCGA-KK-A8I9-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18962ed2-d8fe-4673-a43a-ba1f6aee4efe

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.392G>T p.W131L | Missense Mutation (SNP) | VAF 37/142 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV61653907, COSV61656320; called by muse, mutect2, varscan2
- ADORA3 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99598837; called by muse, mutect2, varscan2
- CUL2 | c.1784G>C p.S595T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101039228; called by muse, mutect2, varscan2
- FAM214A | c.846T>G p.H282Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV99958216; called by muse, mutect2, varscan2
- GLUL | c.329-2A>G p.X110_splice | Splice Site (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100092115; called by muse, mutect2, varscan2
- GOLGB1 | c.1953A>C p.E651D | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100511229; called by muse, mutect2, varscan2
- IFNA17 | c.267T>A p.N89K | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV101303467; called by muse, mutect2, varscan2
- IFT81 | c.1264A>G p.K422E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV99656218; called by muse, mutect2, varscan2
- ITGA10 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as rs782338989, COSV65197837; called by muse, mutect2, varscan2
- KMT2C | c.14534G>C p.R4845T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100074365, COSV51446086; called by muse, varscan2
- KRTAP5-9 | c.506T>G p.I169S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as COSV101603639; called by muse, mutect2, varscan2
- LCOR | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as COSV100603723; called by muse, mutect2
- NIPAL1 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99784494; called by muse, mutect2, varscan2
- PCDHA5 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as COSV65355007; called by muse, mutect2
- PDE9A | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs141486724; called by mutect2, varscan2
- PGM3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99392478; called by muse, mutect2, varscan2
- PHF3 | c.4616A>G p.E1539G | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100013638; called by muse, mutect2, varscan2
- PKD2L1 | c.2027T>C p.I676T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs143580376; called by muse, mutect2, varscan2
- PLXNA2 | c.3630C>G p.H1210Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV100885649, COSV100885836; called by muse, mutect2, varscan2
- POGLUT3 | c.555G>T p.R185S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV100052727; called by muse, mutect2
- PPFIBP2 | c.1490C>G p.P497R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as COSV100206738; called by muse, mutect2
- PTGS2 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772180278, COSV66568344; called by muse, mutect2, varscan2
- REL | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692225; called by mutect2, varscan2
- RRAGA | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV100998139; called by muse, mutect2, varscan2
- SRSF1 | c.80T>A p.I27N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99365437; called by muse, mutect2
- ST8SIA2 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | PolyPhen benign (0.003); catalogued as COSV99184479; called by muse, mutect2, varscan2
- TFAP2E | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138290823; called by muse, mutect2
- LARP4B | c.1455del p.E486Nfs*6 | Frame Shift Del (DEL) | VAF 17/101 reads (17%) | called by mutect2, pindel
- NCAPD3 | c.1490_1493del p.E497Vfs*7 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- ACADS | c.180G>A p.V60= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV99656766; called by muse, mutect2, varscan2
- ADGRE3 | c.246C>T p.N82= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs774575203, COSV99506214; called by muse, mutect2, varscan2
- MTMR2 | c.330T>C p.Y110= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs777436469, COSV100656785; called by muse, mutect2, varscan2
- SRCAP | c.8811A>G p.R2937= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs771344186, COSV52673910; called by muse, mutect2, varscan2
- SRCAP | c.8812A>C p.R2938= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs774472864, COSV52673920; called by muse, mutect2, varscan2
- TPH2 | c.924C>T p.P308= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as rs1343347330, COSV100422186; called by muse, mutect2
- ZFP64 | c.1026T>A p.P342= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99402793; called by muse, mutect2, varscan2
- ZHX2 | c.1974C>T p.Y658= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs199783339, COSV100073506; called by muse, mutect2, varscan2
- ZNF606 | c.291C>T p.H97= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as rs780745480, COSV100357460; called by muse, mutect2, varscan2
